Gene-level copy-number profile of tumor specimen TCGA-53-A4EZ-01A from TCGA case TCGA-53-A4EZ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.5 years (23,201 days).
Specimen TCGA-53-A4EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e4afd82f-7db7-4980-9e85-5da98134f5d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-53-A4EZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d3052998-c123-4477-a0ef-595115b562e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 486; copy number 2: 22,769; copy number 3: 16,229; copy number 4: 14,352; copy number 5: 3,888; copy number 6: 629; copy number 7: 768; copy number 8: 166; copy number 9: 185; copy number 10: 267; copy number 12: 2; copy number 13: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-53-A4EZ-01A-12D-A24O-01): tumor purity 0.47, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,926 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:87,129,765–87,453,373, 5 genes, copy number 6 (within-gene range 3–6): LINC01140, LINC02801, LMO4, LINC01364, RNA5SP52.
- chr1:143,343,180–155,086,807, 520 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr1:201,622,885–201,826,969, 1 gene, copy number 6 (within-gene range 4–6): NAV1.
- chr1:201,688,259–205,022,822, 116 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:223,091,872–223,776,018, 11 genes, copy number 5: AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2.
- chr6:48,701,491–60,546,660, 158 genes, copy number 7 (broad region; genes not listed).
- chr7:56,559,221–57,777,521, 73 genes, copy number 6 (broad region; genes not listed).
- chr7:89,443,946–159,233,377, 1,426 genes, copy number 5 (broad region; genes not listed).
- chr8:40,900,016–97,730,260, 858 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:110,334,743–145,066,685, 534 genes, copy number 6–7 (broad region; genes not listed).
- chr10:4,786,629–5,135,226, 10 genes, copy number 8: AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.
- chr11:66,012,008–67,639,560, 103 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:80,957,317–103,092,194, 374 genes, copy number 5–12 (broad region; genes not listed).
- chr12:30,086,342–38,909,592, 121 genes, copy number 5 (broad region; genes not listed).
- chr12:85,280,220–133,214,832, 1,090 genes, copy number 5–7 (broad region; genes not listed).
- chr16:57,603,137–59,199,395, 55 genes, copy number 5: HMGB3P32, ADGRG1, AC018552.3, ADGRG3, AC018552.2, DRC7, AC018552.1, KATNB1, KIFC3, AC092118.2, MIR6772, AC092118.1, RNU6-20P, CNGB1, TEPP, ZNF319, USB1, MMP15, Y_RNA, AC012182.1, CFAP20, AC026771.1, AC009107.2, CSNK2A2, AC009107.1, RN7SL645P, CCDC113, PRSS54, GINS3, RNU6-269P, AC009118.1, RNU6-1110P, AC009118.2, LINC02137, NDRG4, RNU6-103P, SETD6, CNOT1, AC009118.3, SNORA46, SNORA50A, SNORA50A, AC010287.1, SLC38A7, AC012183.1, GOT2, AC106793.1, RNU6-1155P, RN7SL143P, GEMIN8P2, RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1.
- chr16:80,540,734–81,006,894, 8 genes, copy number 5 (within-gene range 2–5): DYNLRB2, AC108097.1, LINC01227, CDYL2, AC092332.1, AC099313.1, ARLNC1, AC009070.1.
- chr17:19,377,721–22,606,703, 156 genes, copy number 5 (broad region; genes not listed).
- chr20:257,724–2,760,108, 82 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:6,200,989–11,926,609, 70 genes, copy number 5 (broad region; genes not listed).
- chr20:13,995,369–16,053,197, 1 gene, copy number 6 (within-gene range 3–7): MACROD2.
- chr20:14,522,081–15,619,819, 11 genes, copy number 6–7: AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.
- chr20:21,742,303–30,289,956, 143 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
